MMRF case MMRF_1229 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/93061301-28a2-4539-ba6b-cc9fc128b1a2

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 69.0 years (25,212 days); ISS stage: III; Days to last known disease status: 1,593 days (4.4 years); Days to last follow up: 1,593 days (4.4 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 172 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 173 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 183 days; Days to treatment end: 277 days.
   Treatment given: Therapeutic agents: Doxorubicin; Regimen or line of therapy: Liposomal Doxorubicin Regimen; Days to treatment start: 186 days; Days to treatment end: 270 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 311 days; Days to treatment end: 395 days (1.1 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 426 days (1.2 years); Days to treatment end: 427 days (1.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 428 days (1.2 years); Days to treatment end: 428 days (1.2 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Fourth line of therapy; Days to treatment start: 1,538 days (4.2 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,538 days (4.2 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -25 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 11.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 51.2 mg/dL; Immunoglobulin G 2.46 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 20.7 µg/mL; Hemoglobin 5.77 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.55 mmol/L; Albumin 44 g/L; Total Protein 6.3 g/dL; Glucose 5.83 mmol/L.
- Day 59 (ECOG 1): M Protein 0 g/dL; Immunoglobulin G 2.76 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.08 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 94 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 5.4 g/dL; Glucose 5.28 mmol/L.
- Day 143 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 124 mg/dL; Immunoglobulin G 3.68 g/L; Immunoglobulin A 0.2 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 5.95 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.13 mmol/L; Albumin 43 g/L; Total Protein 5.9 g/dL; Glucose 7.59 mmol/L.
- Day 232 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 125 mg/dL; Immunoglobulin G 3.83 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.13 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 166 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 10.4 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 5.89 mmol/L.
- Day 337 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 16.3 mg/dL; Immunoglobulin G 4.93 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 5.9 ×10⁹/L; Platelets 123 ×10⁹/L.
- Day 416 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.327 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.17 mg/dL; Immunoglobulin G 4.7 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.45 mmol/L; Leukocytes 41.1 ×10⁹/L; Absolute Neutrophil 32.8 ×10⁹/L; Platelets 72 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 39.2 g/L; Glucose 4.84 mmol/L.
- Day 505 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.349 mg/dL; Immunoglobulin G 2.91 g/L; Immunoglobulin A 1.78 g/L; Immunoglobulin M 0.26 g/L; Hemoglobin 7.38 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 5.7 g/dL; Glucose 5.01 mmol/L.
- Day 583 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.33 mg/dL; Immunoglobulin G 7.85 g/L; Immunoglobulin A 2 g/L; Immunoglobulin M 0.44 g/L; Hemoglobin 9.11 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 5.6 ×10⁹/L; Platelets 156 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.38 mmol/L; Albumin 48 g/L; Total Protein 7 g/dL; Glucose 5.01 mmol/L.
- Day 654 (ECOG 1): Serum Free Immunoglobulin Light Chain, Lambda 1.53 mg/dL; Immunoglobulin G 8.45 g/L; Immunoglobulin A 1.96 g/L; Immunoglobulin M 0.45 g/L; Hemoglobin 8.25 mmol/L; Leukocytes 7.5 ×10⁹/L; Absolute Neutrophil 5.4 ×10⁹/L; Platelets 147 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 43 g/L; Total Protein 6.8 g/dL; Glucose 5.5 mmol/L.
- Day 821: Immunoglobulin G 10.6 g/L; Immunoglobulin A 2.6 g/L; Immunoglobulin M 0.53 g/L; Beta 2 Microglobulin 4.81 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 5.9 ×10⁹/L; Platelets 184 ×10⁹/L; Creatinine 133 µmol/L; Calcium 2.45 mmol/L.
- Day 866: Serum Free Immunoglobulin Light Chain, Kappa 2.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.3 mg/dL; Immunoglobulin G 11.5 g/L; Immunoglobulin A 2.26 g/L; Immunoglobulin M 0.54 g/L; Beta 2 Microglobulin 4.48 µg/mL; Hemoglobin 7.87 mmol/L; Leukocytes 6.2 ×10⁹/L; Platelets 165 ×10⁹/L; Creatinine 133 µmol/L.
- Day 1,137: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.81 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 1.89 g/L; Immunoglobulin M 0.41 g/L; Hemoglobin 9.05 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 1.4 ×10⁹/L; Platelets 138 ×10⁹/L; Creatinine 133 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 7.21 mmol/L.
- Day 1,508 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 18.5 mg/dL; Immunoglobulin G 7.73 g/L; Immunoglobulin A 1.69 g/L; Immunoglobulin M 0.38 g/L; Beta 2 Microglobulin 4.17 µg/mL; Hemoglobin 9.67 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 5.8 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.45 mmol/L; Albumin 43 g/L; Total Protein 6.3 g/dL; Glucose 8.09 mmol/L.
- Day 1,593 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.45 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.53 mg/dL; Immunoglobulin G 1.98 g/L; Immunoglobulin A 1.36 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 4.21 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 85 ×10⁹/L; Creatinine 141 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2 mmol/L; Albumin 34 g/L; Total Protein 5.1 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day -25: Weight: 95 kg; Height: 187 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Lymphoma.
- Relative with cancer history: yes; Relationship type: Paternal Grandfather; Relationship sex at birth: male.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Leukemia; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (4 samples)
- Sample MMRF_1229_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -25 days.
- Sample MMRF_1229_2_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 59 days.
- Sample MMRF_1229_3_BM_CD138pos: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Days to sample procurement: 232 days.
- Sample MMRF_1229_3_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 232 days.
